Somatic mutation profile of cancer-model specimen HCM-CSHL-0426-C18-85A (3D Organoid; aliquot HCM-CSHL-0426-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-CSHL-0426-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-CSHL-0426-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e4bc397-fe16-4de2-965a-81002d6f0a20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0426-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0426-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abea547a-de69-41c1-a66b-ca4ddd96e6fa

The open-access MAF lists 3,183 somatic variants for this specimen: 2,358 protein-altering or splice-affecting, 681 silent, 144 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,631, Silent 681, Frame Shift Del 471, Frame Shift Ins 117, Nonsense Mutation 95, Intron 90, 3'UTR 20, Splice Region 17, 5'UTR 14, In Frame Del 13, 5'Flank 12, Splice Site 10.

Variants (750 of 3,183; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 99/212 reads (47%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 152/300 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, varscan2
- APC | c.465del p.D156Tfs*14 | Frame Shift Del (DEL) | VAF 108/295 reads (37%) | catalogued as rs1554071529; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 183/476 reads (38%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 126/270 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 91/191 reads (48%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- F8 | c.3637del p.I1213Ffs*5 | Frame Shift Del (DEL) | VAF 150/158 reads (95%) | catalogued as rs387906450, CD111376, CD930955, CX162002, COSV64271598; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FKTN | c.1106del p.F369Sfs*37 | Frame Shift Del (DEL) | VAF 124/302 reads (41%) | catalogued as rs750176716; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 459/1052 reads (44%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 234/569 reads (41%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- LIPA | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 214/487 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776472526, CM993352, CM995150; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MEN1 | c.1561dup p.R521Pfs*15 | Frame Shift Ins (INS) | VAF 306/659 reads (46%) | catalogued as rs767319284; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 117/265 reads (44%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PDK3 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs397515323, CM132388, COSV64792933; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 191/382 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PNPO | c.556C>T p.R186W (on ENST00000225573; = p.R229W on NM_018129.4) | Missense Mutation (SNP) | VAF 283/572 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894629, CM051610; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 100/237 reads (42%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 114/319 reads (36%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RIN2 | c.1878del p.I627Sfs*4 (on ENST00000255006 / NM_001242581.1; = p.I578Sfs*4 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 352/503 reads (70%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RSPH4A | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 166/382 reads (43%) | catalogued as rs755782051, CM1515267, COSV57635223; ClinVar: pathogenic; called by muse, varscan2
- RYR1 | c.6487C>T p.R2163C | Missense Mutation (SNP) | VAF 282/532 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs118192175, CM981780; ClinVar: risk factor / pathogenic / drug response; called by muse, mutect2, varscan2
- SCN2A | c.4876C>T p.R1626* | Nonsense Mutation (SNP) | VAF 240/491 reads (49%) | catalogued as rs1060503102, COSV51837686; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SETD5 | c.3855dup p.S1286Lfs*37 | Frame Shift Ins (INS) | VAF 196/418 reads (47%) | catalogued as rs1553641476; ClinVar: likely pathogenic; called by mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 96/250 reads (38%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TPO | c.2421del p.C808Afs*24 | Frame Shift Del (DEL) | VAF 252/492 reads (51%) | catalogued as rs760307139, COSV100220194; ClinVar: pathogenic; called by mutect2, varscan2
- A2ML1 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 231/448 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367937691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AAMDC | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 202/413 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); catalogued as rs368865821; called by muse, mutect2, varscan2
- AATK | c.3611C>T p.A1204V (on ENST00000326724 / NM_001080395.3; = p.A1101V on NM_004920.2) | Missense Mutation (SNP) | VAF 317/650 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs1338608572; called by muse, mutect2, varscan2
- ABCA13 | c.10508del p.N3503Tfs*28 | Frame Shift Del (DEL) | VAF 170/426 reads (40%) | catalogued as rs759644486; called by mutect2, pindel, varscan2
- ABCA6 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 129/263 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.1); catalogued as COSV52635421; called by muse, mutect2, varscan2
- ABCC1 | c.1345del p.L449Cfs*12 | Frame Shift Del (DEL) | VAF 303/778 reads (39%) | catalogued as rs1567347647; called by mutect2, pindel, varscan2
- ABCC11 | c.3443T>C p.M1148T | Missense Mutation (SNP) | VAF 229/494 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs936473292; called by muse, mutect2, varscan2
- ABCC2 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 233/500 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747449108, COSV64985390; called by muse, mutect2, varscan2
- ABCC4 | c.1310C>A p.P437H | Missense Mutation (SNP) | VAF 196/380 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV65313010; called by muse, mutect2, varscan2
- ABCF3 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 231/476 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs140602070; called by muse, varscan2
- ABCG1 | c.1076del p.G359Vfs*5 | Frame Shift Del (DEL) | VAF 212/546 reads (39%) | catalogued as rs1569239566, CM138401; called by mutect2, pindel, varscan2
- ABHD15 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 300/619 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1165093398; called by muse, varscan2
- ABTB1 | c.712C>T p.R238W (on ENST00000232744 / NM_172027.3; = p.R96W on NM_032548.3) | Missense Mutation (SNP) | VAF 209/447 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs756189995, COSV51739923; called by muse, mutect2, varscan2
- AC099489.1 | c.6653C>T p.T2218I | Missense Mutation (SNP) | VAF 250/553 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.711); catalogued as rs1235267574; called by muse, mutect2, varscan2
- AC100868.1 | c.1030A>C p.K344Q | Missense Mutation (SNP) | VAF 146/352 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.372); catalogued as rs750827898; called by muse, mutect2
- ACADVL | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 199/423 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs374729641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACO2 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 154/326 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV53443990; called by muse, mutect2, varscan2
- ACOT12 | c.1442del p.P481Rfs*63 | Frame Shift Del (DEL) | VAF 95/422 reads (23%) | catalogued as rs752709684; called by mutect2, pindel, varscan2
- ACP6 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 256/524 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs201634452, COSV65077341; called by muse, mutect2, varscan2
- ACSL3 | c.131del p.F44Sfs*17 | Frame Shift Del (DEL) | VAF 148/328 reads (45%) | catalogued as COSV62484662; called by mutect2, pindel, varscan2
- ACSM2A | c.305G>A p.G102D (on ENST00000219054; = p.G23D on NM_001308169.2) | Missense Mutation (SNP) | VAF 276/812 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs745993663; called by muse, varscan2
- ACTN3 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 280/508 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs563563593; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 268/268 reads (100%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 151/324 reads (47%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM12 | c.708del p.V237Lfs*5 | Frame Shift Del (DEL) | VAF 158/397 reads (40%) | catalogued as COSV64108477; called by mutect2, pindel, varscan2
- ADAMTS7 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 206/558 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376444243; called by muse, varscan2
- ADAMTSL1 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 173/367 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs957824765; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 229/444 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1178409619; called by muse, mutect2, varscan2
- ADCY4 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 289/582 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566439285, COSV60258900; called by muse, mutect2, varscan2
- ADCY7 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 198/412 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs754927240, COSV54270471; called by muse, mutect2, varscan2
- ADGRB2 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 232/528 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57079113; called by muse, mutect2, varscan2
- ADGRE1 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 199/392 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.156); catalogued as rs375499219; called by muse, mutect2, varscan2
- ADGRL3 | c.2645T>G p.F882C (on ENST00000506720 / NM_001322402.2; = p.F814C on NM_015236.6) | Missense Mutation (SNP) | VAF 130/277 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101547327; called by muse, mutect2, varscan2
- AEN | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 154/318 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs146671175; called by muse, mutect2, varscan2
- AFAP1L2 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 244/548 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs145837129; called by muse, varscan2
- AGAP1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 149/332 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs373781245; called by muse, mutect2, varscan2
- AGAP1 | c.2059A>G p.S687G (on ENST00000304032 / NM_001037131.3; = p.S634G on NM_014914.5) | Missense Mutation (SNP) | VAF 188/364 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs763397001; called by muse, mutect2, varscan2
- AGRN | c.2780C>T p.T927I | Missense Mutation (SNP) | VAF 327/668 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as rs1298843399, COSV65072296; called by muse, mutect2, varscan2
- ALK | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 276/602 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs779147984, COSV66580573; called by muse, mutect2, varscan2
- ALYREF | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 255/584 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV58669325; called by muse, mutect2, varscan2
- AMER3 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 280/545 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as rs1326472040; called by muse, varscan2
- AMPH | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 157/319 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375161752; called by muse, mutect2, varscan2
- ANGPTL2 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 326/671 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs756824904; called by muse, mutect2, varscan2
- ANK1 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 375/774 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs751082142, COSV55883941; called by muse, mutect2, varscan2
- ANKAR | c.1036del p.S346Qfs*59 | Frame Shift Del (DEL) | VAF 65/167 reads (39%) | catalogued as rs1372933355, COSV55618568; called by mutect2, pindel, varscan2
- ANKRD13C | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 174/370 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs201831251; called by muse, mutect2, varscan2
- ANKRD20A2P | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 168/1076 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1297905824, COSV66464821; called by muse, mutect2, varscan2
- ANPEP | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 246/501 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs367926309; called by muse, mutect2, varscan2
- AOX1 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 231/479 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV65980156; called by muse, mutect2, varscan2
- AP5B1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 207/785 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs778208385; called by muse, mutect2, varscan2
- APBB1IP | c.1799del p.P600Rfs*56 | Frame Shift Del (DEL) | VAF 99/313 reads (32%) | catalogued as rs1314335534; called by mutect2, pindel, varscan2
- APLNR | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 246/540 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.102); catalogued as rs767575528, COSV57243099; called by muse, mutect2, varscan2
- APOA5 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 377/690 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs751198486, COSV57063783; called by muse, mutect2, varscan2
- APOB | c.13412C>T p.A4471V | Missense Mutation (SNP) | VAF 220/442 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as rs749549578, COSV99028730; called by muse, mutect2, varscan2
- ARHGAP20 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 212/454 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs776441588; called by muse, mutect2, varscan2
- ARHGAP45 | c.2344G>A p.V782I | Missense Mutation (SNP) | VAF 317/689 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1355937003; called by muse, mutect2, varscan2
- ARHGEF12 | c.2491A>T p.I831F | Missense Mutation (SNP) | VAF 157/317 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63105869; called by muse, mutect2, varscan2
- ARHGEF6 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 275/275 reads (100%) | catalogued as COSV51690566, COSV51694946; called by muse, mutect2, varscan2
- ARID1A | c.4388G>A p.R1463H | Missense Mutation (SNP) | VAF 284/594 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs752827461, COSV61374560; called by muse, mutect2, varscan2
- ARID5B | c.2386del p.A797Lfs*6 | Frame Shift Del (DEL) | VAF 223/576 reads (39%) | catalogued as rs1044166801; called by mutect2, pindel, varscan2
- ARMC3 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 149/367 reads (41%) | catalogued as rs143785271; called by muse, mutect2, varscan2
- ARMC4 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 239/455 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); catalogued as rs142598573; called by muse, mutect2, varscan2
- ARRDC1 | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 268/543 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs919158801; called by muse, mutect2, varscan2
- ARSI | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 261/522 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1175590084, COSV60816824; called by muse, mutect2, varscan2
- ARTN | c.251A>C p.Q84P (on ENST00000372354; = p.Q92P on NM_057090.2) | Missense Mutation (SNP) | VAF 330/708 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs969549945; called by muse, mutect2, varscan2
- ASCC3 | c.4280C>T p.T1427M | Missense Mutation (SNP) | VAF 269/500 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483972453, COSV64980973; called by muse, mutect2, varscan2
- ASCC3 | c.1058del p.K353Rfs*6 | Frame Shift Del (DEL) | VAF 158/403 reads (39%) | catalogued as rs1361297712; called by mutect2, pindel, varscan2
- ATIC | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 194/409 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs146882973; called by muse, mutect2, varscan2
- ATN1 | c.1443_1448dup p.H482_H483dup | In Frame Ins (INS) | VAF 104/584 reads (18%) | catalogued as rs1160023404; called by mutect2, varscan2
- ATP10A | c.1260G>T p.Q420H | Missense Mutation (SNP) | VAF 248/488 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63513754; called by muse, mutect2, varscan2
- ATP10D | c.2980C>T p.R994* | Nonsense Mutation (SNP) | VAF 209/398 reads (53%) | catalogued as rs200863114; called by muse, mutect2, varscan2
- ATP13A2 | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 307/652 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs190323680; called by muse, mutect2, varscan2
- ATP2B1 | c.805G>T p.G269C | Missense Mutation (SNP) | VAF 210/410 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666023; called by mutect2, varscan2
- ATP2B3 | c.3524del p.P1175Rfs*12 | Frame Shift Del (DEL) | VAF 291/356 reads (82%) | catalogued as rs782513834; called by mutect2, varscan2
- ATP4A | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 289/545 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52868670; called by muse, mutect2, varscan2
- ATP4A | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 290/612 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1282429868, COSV99381931; called by muse, mutect2, varscan2
- ATR | c.3811T>C p.Y1271H | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.076); catalogued as rs1443828723; called by muse, mutect2, varscan2
- ATRNL1 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 145/304 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs140372621; called by muse, mutect2, varscan2
- ATXN7 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 257/539 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs1369874836, COSV55756867; called by muse, mutect2, varscan2
- AXDND1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 175/413 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.286); catalogued as rs200125774, COSV62639986; called by muse, mutect2, varscan2
- AZIN2 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 227/494 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs746470026, COSV53859536, COSV53859589; called by muse, mutect2, varscan2
- B3GNT8 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 217/812 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.27); catalogued as rs758227092, COSV54195368; called by muse, varscan2
- BAIAP2L2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 205/421 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs530602449; called by muse, mutect2, varscan2
- BCL2 | c.132del p.A45Hfs*51 | Frame Shift Del (DEL) | VAF 363/846 reads (43%) | catalogued as COSV61393940; called by mutect2, pindel, varscan2
- BCL2L12 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 277/547 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1372728241; called by muse, mutect2, varscan2
- BCORL1 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 394/394 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs758775339, COSV99500522; called by muse, mutect2, varscan2
- BCORL1 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 349/350 reads (100%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs187190724, COSV99499609; called by muse, mutect2, varscan2
- BMP1 | c.2471G>A p.S824N | Missense Mutation (SNP) | VAF 266/577 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs1373798293, COSV100114774; called by muse, mutect2, varscan2
- BMP8A | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 236/530 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.289); catalogued as rs1426657769; called by muse, mutect2
- BNIP2 | c.670G>T p.G224* | Nonsense Mutation (SNP) | VAF 191/324 reads (59%) | catalogued as COSV99985662; called by muse, mutect2, varscan2
- BNIPL | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 185/449 reads (41%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.754); catalogued as rs757436813; called by muse, varscan2
- BRD4 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 204/485 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs777966382, COSV54584920; called by muse, mutect2, varscan2
- BTBD6 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 301/660 reads (46%) | catalogued as rs749575989; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 230/456 reads (50%) | catalogued as rs752512017; called by mutect2, varscan2
- BTF3L4 | c.135dup p.L46Tfs*5 | Frame Shift Ins (INS) | VAF 94/233 reads (40%) | catalogued as rs1558005082; called by mutect2, varscan2
- BTNL2 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 113/290 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs769178206, COSV100896036; called by muse, mutect2, varscan2
- C16orf54 | c.486del p.A163Pfs*5 | Frame Shift Del (DEL) | VAF 326/830 reads (39%) | catalogued as rs779355314; called by mutect2, pindel, varscan2
- C1orf174 | c.496G>T p.G166W | Missense Mutation (SNP) | VAF 204/405 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV64366181; called by muse, mutect2, varscan2
- C22orf31 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 270/534 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs772347124, COSV53310669; called by muse, mutect2, varscan2
- C3orf80 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 331/699 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.856); catalogued as rs1018775441; called by muse, mutect2, varscan2
- C5 | c.4201C>T p.R1401C | Missense Mutation (SNP) | VAF 144/338 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs145968939; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 192/374 reads (51%) | catalogued as rs372345940; called by mutect2, varscan2
- C8orf34 | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 197/392 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs190887237; called by muse, mutect2, varscan2
- CA11 | c.916del p.R306Gfs*51 | Frame Shift Del (DEL) | VAF 279/670 reads (42%) | catalogued as COSV50033830; called by mutect2, pindel, varscan2
- CABIN1 | c.4784C>T p.P1595L | Missense Mutation (SNP) | VAF 266/583 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV54078643; called by muse, mutect2, varscan2
- CACNA1B | c.6979C>T p.R2327W | Missense Mutation (SNP) | VAF 259/575 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765789569, COSV53142151; called by muse, mutect2, varscan2
- CACNA1D | c.6070T>G p.W2024G (on ENST00000350061 / NM_001128840.3; = p.W2044G on NM_000720.4) | Missense Mutation (SNP) | VAF 303/633 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV99860849; called by muse, mutect2, varscan2
- CACNA1E | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 368/748 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.351); catalogued as rs374689888, COSV62395329; called by muse, mutect2, varscan2
- CACNA1H | c.6503C>T p.A2168V | Missense Mutation (SNP) | VAF 369/821 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs765008315; called by muse, mutect2, varscan2
- CACNG6 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 470/944 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs746712453; called by muse, mutect2, varscan2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 314/824 reads (38%) | catalogued as rs745648688, COSV53168096; called by mutect2, pindel, varscan2
- CACNG7 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 270/528 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs369839062, COSV99712202; called by muse, mutect2, varscan2
- CACTIN | c.1819_1821del p.F607del | In Frame Del (DEL) | VAF 287/617 reads (47%) | catalogued as rs751667810; called by pindel, varscan2
- CADPS | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 290/596 reads (49%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs751422032; called by muse, mutect2, varscan2
- CALD1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 175/371 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1267886086, COSV62649429, COSV62650905; called by muse, mutect2, varscan2
- CAMSAP2 | c.1370G>A p.R457Q (on ENST00000236925 / NM_001297707.2; = p.R446Q on NM_203459.3) | Missense Mutation (SNP) | VAF 133/268 reads (50%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.749); catalogued as rs146524997, COSV52668223; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 150/320 reads (47%) | catalogued as rs1375954479; called by mutect2, varscan2
- CAMTA1 | c.2602G>A p.G868R | Missense Mutation (SNP) | VAF 222/486 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.887); catalogued as rs770924661; called by muse, mutect2, varscan2
- CAPN7 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 141/267 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99512517; called by muse, mutect2, varscan2
- CARD8 | c.1085C>T p.S362L (on ENST00000651546 / NM_001184900.3; = p.S312L on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 185/383 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764264265; called by muse, mutect2, varscan2
- CARMIL1 | c.1829_1831del p.N610del | In Frame Del (DEL) | VAF 88/262 reads (34%) | catalogued as rs764270535; called by pindel, varscan2
- CARMIL2 | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 413/868 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs749823173; called by muse, mutect2, varscan2
- CARMIL3 | c.3103G>A p.V1035M | Missense Mutation (SNP) | VAF 268/536 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs542450759; called by muse, mutect2, varscan2
- CASP8 | c.1068del p.F356Lfs*26 (on ENST00000432109 / NM_033355.3; = p.F373Lfs*26 on NM_001228.4) | Frame Shift Del (DEL) | VAF 170/418 reads (41%) | catalogued as COSV51847031; called by mutect2, pindel, varscan2
- CATSPER1 | c.2141C>T p.A714V | Missense Mutation (SNP) | VAF 202/430 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764683817, COSV56412480; called by muse, mutect2, varscan2
- CAV1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 202/465 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs143730366; called by muse, mutect2, varscan2
- CAVIN2 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 264/536 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as rs762124159, COSV58423626; called by muse, mutect2, varscan2
- CBX2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 19/697 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs782145802, COSV53968469; called by muse, mutect2
- CC2D1A | c.2693del p.G898Vfs*45 | Frame Shift Del (DEL) | VAF 234/570 reads (41%) | catalogued as rs1423002835; called by mutect2, pindel, varscan2
- CCBE1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 226/458 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs115982879, COSV67949322; called by muse, mutect2, varscan2
- CCDC116 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 228/474 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs1166702926; called by muse, mutect2, varscan2
- CCDC12 | c.401C>T p.A134V (on ENST00000425441 / NM_001277074.1; = p.A147V on NM_144716.5) | Missense Mutation (SNP) | VAF 246/499 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52765364; called by muse, mutect2, varscan2
- CCDC127 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 213/488 reads (44%) | catalogued as rs1204741024; called by muse, mutect2, varscan2
- CCDC137 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 346/737 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1286033386; called by muse, varscan2
- CCDC168 | c.16334C>T p.T5445M | Missense Mutation (SNP) | VAF 231/438 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs144201982, COSV100487667; called by muse, mutect2, varscan2
- CCDC168 | c.12265G>A p.A4089T | Missense Mutation (SNP) | VAF 114/420 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs760630397; called by muse, mutect2, varscan2
- CCDC168 | c.323del p.L108* | Frame Shift Del (DEL) | VAF 78/206 reads (38%) | catalogued as rs34318963; called by mutect2, pindel, varscan2
- CCDC17 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 211/453 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs749435522, COSV59647674; called by muse, mutect2, varscan2
- CCDC185 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 228/518 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs765942457; called by muse, varscan2
- CCDC40 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 70/428 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs1052358414, COSV66473301; called by muse, varscan2
- CCDC57 | c.2599G>A p.V867I | Missense Mutation (SNP) | VAF 230/520 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs369435465; called by muse, mutect2, varscan2
- CCDC77 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 239/483 reads (49%) | catalogued as rs762749495; called by muse, mutect2, varscan2
- CCDC80 | c.1658del p.K553Rfs*2 | Frame Shift Del (DEL) | VAF 198/439 reads (45%) | catalogued as rs1253078189; called by mutect2, varscan2
- CCDC80 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 209/436 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs565610574, COSV52820247; called by muse, mutect2, varscan2
- CD200R1 | c.161C>A p.A54D (on ENST00000471858 / NM_170780.3; = p.A77D on NM_138806.4) | Missense Mutation (SNP) | VAF 178/322 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55603254; called by muse, mutect2, varscan2
- CD300LG | c.651dup p.M218Hfs*21 | Frame Shift Ins (INS) | VAF 214/476 reads (45%) | catalogued as rs760923345; called by mutect2, varscan2
- CDAN1 | c.1706G>A p.G569D | Missense Mutation (SNP) | VAF 170/396 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.194); catalogued as rs373357147; called by muse, mutect2, varscan2
- CDC42BPA | c.3004G>A p.G1002S (on ENST00000334218 / NM_001366019.2; = p.G989S on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/279 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99043556; called by muse, mutect2, varscan2
- CDCA3 | c.257del p.P86Qfs*5 | Frame Shift Del (DEL) | VAF 137/359 reads (38%) | catalogued as rs782448572; called by mutect2, pindel, varscan2
- CDCA4 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 309/642 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs549418658, COSV60314955; called by muse, mutect2, varscan2
- CDCP1 | c.1840del p.R614Gfs*38 | Frame Shift Del (DEL) | VAF 220/568 reads (39%) | catalogued as COSV56104487; called by mutect2, pindel, varscan2
- CDH18 | c.1327A>G p.T443A | Missense Mutation (SNP) | VAF 160/374 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1409678142, COSV99937796; called by muse, mutect2, varscan2
- CDH9 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 156/367 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.196); catalogued as rs1265659383; called by muse, mutect2, varscan2
- CDHR5 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 170/376 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV62764042; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 254/534 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs746203438, COSV62573211, COSV62573947; called by muse, mutect2, varscan2
- CEMIP | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 233/505 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.917); catalogued as rs759087523; called by muse, mutect2, varscan2
- CENPJ | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs369635681, COSV67883116, COSV67883522; called by muse, mutect2, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 78/176 reads (44%) | catalogued as rs769310263; called by mutect2, varscan2
- CEP131 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 245/519 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359607113; called by muse, mutect2, varscan2
- CEP170B | c.1933del p.Q645Rfs*179 (on ENST00000453495; = p.Q574Rfs*179 on NM_015005.3) | Frame Shift Del (DEL) | VAF 228/593 reads (38%) | catalogued as rs1431118175; called by mutect2, pindel, varscan2
- CEP250 | c.7127G>A p.R2376H | Missense Mutation (SNP) | VAF 260/529 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs374274791, COSV61168872, COSV61170900; called by muse, varscan2
- CEP295 | c.5707G>A p.V1903I | Missense Mutation (SNP) | VAF 163/374 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1212253453, COSV57349551; called by muse, varscan2
- CEP76 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 136/288 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs755171008; called by muse, mutect2, varscan2
- CEP97 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 197/427 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374438407; called by muse, mutect2, varscan2
- CFAP410 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 262/648 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1251364740; called by muse, mutect2
- CFAP44 | c.3423del p.E1142Nfs*35 | Frame Shift Del (DEL) | VAF 128/350 reads (37%) | catalogued as rs947129972; called by pindel, varscan2
- CFAP46 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 224/473 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1180604344; called by muse, mutect2
- CFHR3 | c.329C>A p.T110K | Missense Mutation (SNP) | VAF 154/312 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.317); catalogued as rs1238197794; called by muse, mutect2, varscan2
- CGAS | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 132/279 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149902826, COSV100943685; called by muse, varscan2
- CHAT | c.203dup p.P69Tfs*12 | Frame Shift Ins (INS) | VAF 240/512 reads (47%) | catalogued as rs1157881522; called by mutect2, varscan2
- CHD7 | c.3745C>T p.R1249W | Missense Mutation (SNP) | VAF 172/376 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1050617514; called by muse, mutect2, varscan2
- CHD9 | c.6866C>T p.A2289V | Missense Mutation (SNP) | VAF 212/434 reads (49%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.788); catalogued as rs1338867336; called by muse, mutect2, varscan2
- CHP2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 225/506 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.083); catalogued as rs758157005; called by muse, mutect2, varscan2
- CHRNA3 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 256/596 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775325162, COSV100468651, COSV58775586; called by muse, mutect2
- CHRNB4 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 294/593 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs199844639, COSV99929417; called by muse, varscan2
- CHST13 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 358/704 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1231021325, COSV60043121; called by muse, mutect2, varscan2
- CHTF18 | c.1487C>A p.P496Q | Missense Mutation (SNP) | VAF 236/510 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746734598; called by muse, mutect2, varscan2
- CIAO3 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 288/607 reads (47%) | catalogued as rs575691401, COSV52405327; called by muse, varscan2
- CIITA | c.1812_1814del p.L605del | In Frame Del (DEL) | VAF 210/452 reads (46%) | catalogued as rs1432967208; called by pindel, varscan2
- CIZ1 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 205/403 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs760065353, COSV99477255; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 40/170 reads (24%) | catalogued as rs752250702; called by mutect2, varscan2
- CKB | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 325/699 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs773350958; called by muse, mutect2, varscan2
- CLEC4D | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 145/291 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs139845503; called by muse, mutect2, varscan2
- CLGN | c.822dup p.P275Tfs*2 | Frame Shift Ins (INS) | VAF 175/431 reads (41%) | catalogued as rs1442881852; called by mutect2, pindel, varscan2
- CLIC6 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 320/626 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs996635682, COSV100659314; called by muse, varscan2
- CLRN3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 179/376 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs371220164; called by muse, mutect2, varscan2
- CLSPN | c.3565C>T p.Q1189* | Nonsense Mutation (SNP) | VAF 84/193 reads (44%) | catalogued as rs1339597031, COSV52050017; called by muse, mutect2, varscan2
- CLUH | c.92C>T p.P31L (on ENST00000435359; = p.P69L on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 313/656 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs758323365; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 121/265 reads (46%) | catalogued as rs758676375; called by mutect2, varscan2
- COG2 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs770865600, COSV64186090; called by muse, mutect2, varscan2
- COL11A1 | c.2098G>C p.G700R | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614689; called by muse, mutect2, varscan2
- COL11A2 | c.4939G>A p.A1647T (on ENST00000341947 / NM_080680.3; = p.A1540T on NM_080679.2) | Missense Mutation (SNP) | VAF 30/1008 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs779453008; called by muse, mutect2
- COL13A1 | c.1550del p.P517Qfs*9 (on ENST00000398978 / NM_001130103.2; = p.P460Qfs*9 on NM_080798.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 198/493 reads (40%) | catalogued as rs770933186, COSV100637433; called by mutect2, pindel, varscan2
- COL14A1 | c.2137C>T p.L713F | Missense Mutation (SNP) | VAF 136/282 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs146557532, COSV52870688; called by muse, mutect2, varscan2
- COL14A1 | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 161/360 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs781191822, COSV52848407; called by muse, mutect2, varscan2
- COL15A1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 265/514 reads (52%) | SIFT tolerated (0.98); PolyPhen benign (0.057); catalogued as rs570016118, COSV66642410; called by muse, mutect2, varscan2
- COL1A1 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as CM137813; called by muse, mutect2, varscan2
- COL22A1 | c.2386C>T p.R796* | Nonsense Mutation (SNP) | VAF 27/521 reads (5%) | catalogued as rs373752145, COSV100281308; called by muse, mutect2
- COL28A1 | c.1733G>A p.G578D | Missense Mutation (SNP) | VAF 225/458 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68084205; called by muse, mutect2, varscan2
- COL3A1 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 143/298 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1485092842, COSV100483994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A3 | c.2843C>T p.S948F | Missense Mutation (SNP) | VAF 143/307 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs927872112, COSV59258281; called by muse, mutect2, varscan2
- COL5A3 | c.4525G>A p.V1509M | Missense Mutation (SNP) | VAF 308/601 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs1329233852; called by muse, mutect2, varscan2
- COL5A3 | c.3560G>C p.G1187A | Missense Mutation (SNP) | VAF 260/524 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1228070058; called by muse, mutect2
- COL6A3 | c.8047G>A p.V2683M | Missense Mutation (SNP) | VAF 258/537 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1037630319; called by muse, mutect2, varscan2
- COL6A3 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 291/611 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs374447921, COSV99799860; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL6A5 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 215/443 reads (49%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.759); catalogued as rs146510478; called by muse, mutect2
- COL8A1 | c.1631del p.P544Qfs*30 | Frame Shift Del (DEL) | VAF 227/597 reads (38%) | catalogued as COSV53736505; called by mutect2, pindel, varscan2
- CORO6 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 208/442 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375611970; called by muse, mutect2, varscan2
- CPED1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 167/359 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV60004265; called by muse, mutect2, varscan2
- CPN1 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 210/438 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753854211; called by muse, mutect2, varscan2
- CPQ | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 169/390 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); catalogued as rs776801209; called by muse, mutect2, varscan2
- CPSF7 | c.806del p.P269Hfs*43 (on ENST00000394888 / NM_001136040.4; = p.P312Hfs*43 on NM_024811.4) | Frame Shift Del (DEL) | VAF 335/764 reads (44%) | catalogued as rs1429447472; called by mutect2, pindel, varscan2
- CREBBP | c.7162G>A p.A2388T | Missense Mutation (SNP) | VAF 294/636 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); catalogued as rs756011865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CREBBP | c.4990C>T p.R1664C | Missense Mutation (SNP) | VAF 326/723 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52114474; called by muse, mutect2, varscan2
- CREM | c.860G>A p.R287H (on ENST00000429130; = p.R242H on NM_181571.3) | Missense Mutation (SNP) | VAF 130/286 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs936104894, COSV100415437; called by muse, varscan2
- CRYBB1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 45/603 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs754411906, COSV53232510; called by muse, mutect2
- CSF2RB | c.1701del p.S568Afs*130 | Frame Shift Del (DEL) | VAF 328/871 reads (38%) | catalogued as rs757082963; called by mutect2, pindel, varscan2
- CSMD1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 234/451 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs374230800; called by muse, mutect2, varscan2
- CT47B1 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 103/164 reads (63%) | catalogued as rs1339926372; called by muse, mutect2, varscan2
- CTDP1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 189/420 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs1028353134, COSV99310889; called by muse, mutect2, varscan2
- CTRB2 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.068); catalogued as rs1235720810; called by muse, mutect2, varscan2
- CTSV | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV52344574; called by muse, mutect2, varscan2
- CUL3 | c.1358del p.N453Tfs*2 | Frame Shift Del (DEL) | VAF 115/281 reads (41%) | catalogued as rs1366667901; called by mutect2, pindel, varscan2
- CWC25 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 116/280 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305852779; called by muse, mutect2, varscan2
- CYB5D2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 171/341 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1197999512, COSV56802064; called by muse, mutect2, varscan2
- CYLC2 | c.747del p.D250Mfs*106 | Frame Shift Del (DEL) | VAF 161/319 reads (50%) | catalogued as COSV100872458; called by mutect2, varscan2
- CYP11B1 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 225/540 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1158616210; called by muse, mutect2, varscan2
- CYP21A2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 156/719 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs72552757, CM022200; called by muse, mutect2, varscan2
- CYP26C1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 382/723 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs746340948; called by muse, mutect2, varscan2
- CYP4F22 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 152/352 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs561480298, COSV54106195; called by muse, mutect2, varscan2
- DAAM2 | c.2698C>T p.R900C (on ENST00000274867 / NM_001201427.2; = p.R899C on NM_015345.3) | Missense Mutation (SNP) | VAF 126/261 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1047541318, COSV51313148; called by muse, mutect2, varscan2
- DACH2 | c.1573del p.T525Pfs*33 | Frame Shift Del (DEL) | VAF 274/378 reads (72%) | catalogued as COSV100912973, COSV64169192; called by mutect2, pindel, varscan2
- DAPK3 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 388/810 reads (48%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs1190048528, COSV56663236; called by muse, mutect2, varscan2
- DBX1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 199/399 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57053677; called by muse, mutect2
- DCAF1 | c.2809dup p.Q937Pfs*20 | Frame Shift Ins (INS) | VAF 214/457 reads (47%) | catalogued as rs782606429; called by mutect2, varscan2
- DCC | c.3863C>T p.S1288L | Missense Mutation (SNP) | VAF 227/457 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.155); catalogued as COSV101472307; called by muse, mutect2, varscan2
- DCDC1 | c.4396C>T p.R1466C (on ENST00000597505 / NM_001367979.1; = p.R573C on NM_020869.3) | Missense Mutation (SNP) | VAF 150/342 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs761430464, COSV100337933, COSV100338441, COSV57998997; called by muse, mutect2, varscan2
- DCSTAMP | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 162/374 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs749718466; called by muse, mutect2, varscan2
- DDX50 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 95/203 reads (47%) | catalogued as rs142295291; called by muse, mutect2, varscan2
- DDX58 | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 160/346 reads (46%) | catalogued as rs773422076, COSV65883152; called by muse, mutect2, varscan2
- DENND2B | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 286/590 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142799946, COSV58201975; called by muse, mutect2, varscan2
- DENND6A | c.1074del p.F358Lfs*14 | Frame Shift Del (DEL) | VAF 143/374 reads (38%) | catalogued as rs34959359; called by mutect2, pindel, varscan2
- DGKD | c.2564dup p.T856Yfs*5 (on ENST00000264057 / NM_152879.3; = p.T812Yfs*5 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 184/354 reads (52%) | catalogued as rs35538077; called by mutect2, varscan2
- DICER1 | c.3308A>T p.D1103V | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs1566769521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIP2A | c.2875del p.V959Lfs*49 | Frame Shift Del (DEL) | VAF 158/397 reads (40%) | catalogued as COSV59477609; called by mutect2, pindel, varscan2
- DIP2B | c.732dup p.S245Lfs*5 | Frame Shift Ins (INS) | VAF 233/596 reads (39%) | catalogued as rs1270852059; called by mutect2, pindel, varscan2
- DISP3 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 243/543 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1186903277, COSV53819377; called by muse, mutect2, varscan2
- DLG1 | c.2098G>A p.V700I (on ENST00000419354 / NM_001290983.1; = p.V722I on NM_004087.2) | Missense Mutation (SNP) | VAF 144/318 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs556519100; called by muse, mutect2, varscan2
- DLGAP1 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 379/788 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192982479; called by muse, mutect2, varscan2
- DLX4 | c.340G>A p.A114T (on ENST00000240306 / NM_138281.3; = p.A42T on NM_001934.3) | Missense Mutation (SNP) | VAF 381/788 reads (48%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs780722446; called by muse, varscan2
- DMRTC2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 193/369 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs782073409, COSV99523260; called by muse, mutect2, varscan2
- DMWD | c.185del p.P62Rfs*149 | Frame Shift Del (DEL) | VAF 450/1113 reads (40%) | catalogued as rs1384560335; called by mutect2, pindel, varscan2
- DMXL1 | c.7706G>A p.R2569H | Missense Mutation (SNP) | VAF 195/390 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750990275, COSV60704181; called by muse, mutect2, varscan2
- DNAH11 | c.13240dup p.T4414Nfs*34 | Frame Shift Ins (INS) | VAF 220/434 reads (51%) | catalogued as rs759332741; called by mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 66/164 reads (40%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH17 | c.13181C>T p.A4394V | Missense Mutation (SNP) | VAF 169/380 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs564517631; called by muse, varscan2
- DNAH17 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 142/350 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs199854936, COSV101101931; called by muse, mutect2, varscan2
- DNAH17 | c.2401G>T p.A801S | Missense Mutation (SNP) | VAF 139/285 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs188562373; called by muse, mutect2, varscan2
- DNAH2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 182/413 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50020974; called by muse, mutect2, varscan2
- DNAH2 | c.7147G>A p.A2383T | Missense Mutation (SNP) | VAF 114/241 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs760670678, COSV66724474; called by muse, mutect2, varscan2
- DNAH3 | c.11875G>A p.G3959R | Missense Mutation (SNP) | VAF 146/321 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99769043; called by muse, mutect2, varscan2
- DNAJA2 | c.204A>T p.R68S | Missense Mutation (SNP) | VAF 178/417 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1197667183; called by muse, mutect2, varscan2
- DNAJB14 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 222/464 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV62036464; called by muse, mutect2, varscan2
- DNAJC22 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 120/253 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as rs200327446, COSV101222508; called by muse, mutect2, varscan2
- DNASE1 | c.25del p.A9Rfs*15 | Frame Shift Del (DEL) | VAF 241/581 reads (41%) | catalogued as rs746491054; called by mutect2, pindel, varscan2
- DNMT3A | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 118/505 reads (23%) | catalogued as rs759187608, COSV53043586; called by muse, mutect2, varscan2
- DOCK10 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 148/326 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs760214174; called by muse, mutect2, varscan2
- DPP4 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 213/437 reads (49%) | catalogued as rs745777648, COSV62106316; called by muse, mutect2, varscan2
- DPP6 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 114/246 reads (46%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as rs892507991; called by muse, varscan2
- DPYS | c.35del p.G12Vfs*86 | Frame Shift Del (DEL) | VAF 294/739 reads (40%) | catalogued as rs1212167138; called by mutect2, pindel, varscan2
- DSCAML1 | c.5284G>A p.V1762I (on ENST00000321322; = p.V1702I on NM_020693.4) | Missense Mutation (SNP) | VAF 246/554 reads (44%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.984); catalogued as rs147907435; called by muse, mutect2, varscan2
- DTWD1 | c.503del p.N168Mfs*22 | Frame Shift Del (DEL) | VAF 196/449 reads (44%) | catalogued as rs1412686031; called by mutect2, pindel, varscan2
- DUOX1 | c.3503C>T p.P1168L | Missense Mutation (SNP) | VAF 197/516 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58478395; called by muse, mutect2, varscan2
- DUSP8 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 359/690 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs766200658; called by muse, mutect2, varscan2
- DYNC2I1 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 215/395 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1297205333; called by muse, varscan2
- E2F1 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 161/340 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as rs183250565, COSV99864845; called by muse, mutect2, varscan2
- ECE1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 400/784 reads (51%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.586); catalogued as rs1049897620; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1237C>T p.R413* (on ENST00000361735 / NM_015935.5; = p.R327* on NM_014955.3) | Nonsense Mutation (SNP) | VAF 156/305 reads (51%) | catalogued as rs963906263; called by muse, mutect2, varscan2
- EFCAB6 | c.4039G>T p.D1347Y | Missense Mutation (SNP) | VAF 122/268 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV53069566; called by muse, mutect2, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 179/459 reads (39%) | catalogued as rs745309220; called by mutect2, pindel, varscan2
- EGFR | c.2839A>G p.M947V | Missense Mutation (SNP) | VAF 133/273 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368698152; called by muse, mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 327/812 reads (40%) | catalogued as rs1377283633; called by mutect2, pindel, varscan2
- EIF3A | c.795del p.K265Nfs*7 | Frame Shift Del (DEL) | VAF 152/412 reads (37%) | catalogued as rs34481774; called by mutect2, pindel, varscan2
- EIF3A | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 173/348 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64963353, COSV64963460; called by muse, mutect2, varscan2
- EIF3C | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 269/1123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374480438, COSV59059672; called by muse, mutect2, varscan2
- EIF4A1 | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 147/295 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1283063684; called by muse, mutect2, varscan2
- ELFN2 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 278/581 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV68744093; called by muse, mutect2, varscan2
- ELP5 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 225/494 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV59708561; called by muse, mutect2, varscan2
- ENG | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 266/566 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs757113987; called by muse, varscan2
- ENTPD8 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 191/405 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as rs578205858, COSV58161914; called by muse, mutect2, varscan2
- EP400 | c.7139G>A p.R2380H | Missense Mutation (SNP) | VAF 240/533 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1395587120, COSV57770513; called by muse, mutect2, varscan2
- EPB41L3 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 170/381 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs769159490, COSV59461373; called by muse, mutect2, varscan2
- EPHA10 | c.650del p.G217Afs*132 (on ENST00000373048 / NM_001099439.2; = p.G217Afs*82 on NM_173641.2) | Frame Shift Del (DEL) | VAF 317/803 reads (39%) | catalogued as COSV57624618; called by mutect2, pindel, varscan2
- EPM2A | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 261/528 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62296224; called by muse, mutect2, varscan2
- EPS8L3 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.776); catalogued as rs746842011, COSV62609143; called by muse, mutect2, varscan2
- EPX | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 155/347 reads (45%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.931); catalogued as rs144998259; called by muse, mutect2, varscan2
- ERBB3 | c.1999C>A p.R667S | Missense Mutation (SNP) | VAF 216/386 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57247893, COSV57261351; called by muse, varscan2
- ERFE | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 277/533 reads (52%) | SIFT deleterious, low confidence (0); catalogued as rs772260697; called by muse, mutect2, varscan2
- ERFL | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 363/755 reads (48%) | SIFT tolerated, low confidence (0.07); catalogued as rs992568720; called by muse, mutect2, varscan2
- ERGIC2 | c.25del p.T9Lfs*2 | Frame Shift Del (DEL) | VAF 147/368 reads (40%) | catalogued as rs1370236096; called by mutect2, pindel, varscan2
- ERICH4 | c.64dup p.Q22Pfs*29 | Frame Shift Ins (INS) | VAF 214/438 reads (49%) | catalogued as rs567420399; called by mutect2, varscan2
- ERVFRD-1 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 132/275 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs768463887, COSV65369528; called by muse, mutect2, varscan2
- ERVMER34-1 | c.1103A>G p.D368G | Missense Mutation (SNP) | VAF 204/418 reads (49%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as COSV66920735; called by muse, mutect2, varscan2
- EVC2 | c.3151G>A p.V1051M | Missense Mutation (SNP) | VAF 356/676 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs775917298; called by muse, mutect2, varscan2
- EVX1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 77/505 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs867878464; called by muse, mutect2, varscan2
- EXOC6B | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 162/363 reads (45%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); catalogued as rs766170220, COSV55566619, COSV99723156; called by muse, mutect2, varscan2
- EYA1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 221/506 reads (44%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.882); catalogued as rs181191349; ClinVar: benign; called by muse, mutect2, varscan2
- F10 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs751623132, COSV65021899; called by muse, mutect2, varscan2
- FAM117B | c.1144dup p.L382Pfs*6 | Frame Shift Ins (INS) | VAF 178/364 reads (49%) | catalogued as rs761783143; called by mutect2, varscan2
- FAM131A | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 354/656 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs759559677; called by muse, mutect2, varscan2
- FAM20C | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 462/907 reads (51%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1437202079; called by muse, mutect2, varscan2
- FAM221B | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 145/307 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1013222665, COSV52414614; called by muse, mutect2, varscan2
- FAM221B | c.62del p.P21Lfs*20 | Frame Shift Del (DEL) | VAF 231/571 reads (40%) | catalogued as rs1323115063, COSV65073645, COSV65075016; called by mutect2, pindel, varscan2
- FAM71C | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 180/413 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs760259280; called by muse, mutect2, varscan2
- FAM89A | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 154/318 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767532073, COSV100792581; called by muse, mutect2, varscan2
- FAN1 | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 270/521 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1452542279; called by muse, mutect2, varscan2
- FASTKD5 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 168/347 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs772486694, COSV99418845; called by muse, mutect2, varscan2
- FAT2 | c.11533C>T p.R3845C | Missense Mutation (SNP) | VAF 207/438 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.448); catalogued as rs762295424; called by muse, mutect2, varscan2
- FAT4 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 38/561 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV67891450; called by muse, mutect2
- FBLN2 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 212/774 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777965029; called by muse, varscan2
- FBN1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 174/384 reads (45%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.959); catalogued as rs749989129, COSV57313314; called by muse, mutect2, varscan2
- FBXL22 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 213/428 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs758363206; called by muse, mutect2, varscan2
- FCRL2 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 131/311 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV63832525; called by muse, mutect2, varscan2
- FCSK | c.3043del p.H1015Tfs*19 | Frame Shift Del (DEL) | VAF 270/707 reads (38%) | catalogued as rs754711319; called by mutect2, pindel, varscan2
- FER1L6 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 239/506 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67548321; called by muse, mutect2, varscan2
- FEZF1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 169/350 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV58659765; called by muse, mutect2, varscan2
- FEZF2 | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 394/802 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.791); catalogued as COSV99032474; called by muse, mutect2, varscan2
- FGB | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 50/399 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs775243595; called by muse, mutect2, varscan2
- FGD5 | c.3095C>T p.A1032V | Missense Mutation (SNP) | VAF 213/429 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758570732, COSV53240556; called by muse, mutect2, varscan2
- FGF11 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 183/362 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53440373; called by muse, mutect2, varscan2
- FGF2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 381/752 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52648902; called by muse, mutect2, varscan2
- FGF3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 357/681 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as rs1156753470, COSV61926245; called by muse, mutect2, varscan2
- FHOD3 | c.863G>A p.C288Y | Missense Mutation (SNP) | VAF 169/371 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV99068633; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 220/543 reads (41%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIGLA | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 352/744 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60089432; called by muse, mutect2, varscan2
- FKRP | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 301/596 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1450841129, CM013809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.2072C>T p.T691I | Missense Mutation (SNP) | VAF 203/409 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV57956871; called by muse, mutect2, varscan2
- FLNC | c.2888del p.P963Rfs*26 | Frame Shift Del (DEL) | VAF 240/598 reads (40%) | catalogued as rs764460165; called by mutect2, pindel, varscan2
- FMNL1 | c.886T>C p.F296L | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs752976420; called by muse, mutect2, varscan2
- FNDC10 | c.290del p.P97Rfs*91 | Frame Shift Del (DEL) | VAF 313/833 reads (38%) | catalogued as rs1334264965; called by mutect2, pindel, varscan2
- FOLH1 | c.1501del p.S501Vfs*12 | Frame Shift Del (DEL) | VAF 101/281 reads (36%) | catalogued as rs764290022, COSV57049642; called by mutect2, pindel, varscan2
- FOXP1 | c.1768A>G p.M590V | Missense Mutation (SNP) | VAF 202/437 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs201446635; called by muse, mutect2, varscan2
- FOXP1 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 129/253 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59541468; called by muse, mutect2, varscan2
- FOXP2 | c.1961G>A p.S654N | Missense Mutation (SNP) | VAF 174/369 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs768186362, COSV100646084; called by muse, mutect2, varscan2
- FOXQ1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 484/958 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.108); catalogued as rs996666315; called by muse, mutect2, varscan2
- FOXRED1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 134/286 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs150427279; called by muse, mutect2, varscan2
- FRMD3 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 123/289 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435490016, COSV58461025; called by muse, mutect2, varscan2
- FRMD4A | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 200/441 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as rs772563228, COSV52717882; called by muse, mutect2, varscan2
- FTHL17 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 311/311 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs756401411; called by muse, mutect2, varscan2
- FTSJ3 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 289/613 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs749821889; called by muse, mutect2, varscan2
- FUT4 | c.741del p.D248Tfs*48 | Frame Shift Del (DEL) | VAF 827/1184 reads (70%) | catalogued as rs746338726; called by mutect2, pindel, varscan2
- FZD3 | c.888dup p.T297Yfs*25 | Frame Shift Ins (INS) | VAF 172/364 reads (47%) | catalogued as rs765036679; called by mutect2, varscan2
- GABRQ | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 248/248 reads (100%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.781); catalogued as rs782073807, COSV64783672; called by muse, mutect2, varscan2
- GAL3ST3 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 278/592 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs1253031284; called by muse, varscan2
- GALNS | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 231/529 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs372585484; called by muse, mutect2, varscan2
- GALNT12 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 120/501 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as rs920049418, CM094555, COSV66662942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT2 | c.80del p.G27Afs*115 | Frame Shift Del (DEL) | VAF 320/813 reads (39%) | catalogued as rs1553309006; called by mutect2, pindel, varscan2
- GALT | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 256/586 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM074211; called by muse, mutect2, varscan2
- GAS6 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 288/619 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as rs202234400; called by muse, mutect2
- GATA5 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 250/564 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556876322; called by muse, mutect2, varscan2
- GBP3 | c.639del p.D214Ifs*51 | Frame Shift Del (DEL) | VAF 102/282 reads (36%) | catalogued as rs1557727607; called by mutect2, pindel, varscan2
- GCAT | c.818del p.X273_splice | Splice Site (DEL) | VAF 162/418 reads (39%) | catalogued as rs1569083487; called by mutect2, pindel, varscan2
- GCKR | c.323del p.G108Afs*17 | Frame Shift Del (DEL) | VAF 244/655 reads (37%) | catalogued as COSV99253866; called by mutect2, pindel, varscan2
- GCN1 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 242/550 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs575068347; called by muse, mutect2, varscan2
- GDF1 | c.933del p.P312Rfs*73 | Frame Shift Del (DEL) | VAF 382/960 reads (40%) | catalogued as rs1213194580; called by mutect2, pindel, varscan2
- GDF10 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 327/657 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1555206775; called by muse, mutect2, varscan2
- GFRAL | c.300del p.K100Nfs*9 | Frame Shift Del (DEL) | VAF 114/282 reads (40%) | catalogued as rs755972268; called by mutect2, pindel, varscan2
- GGH | c.825dup p.V276Cfs*2 | Frame Shift Ins (INS) | VAF 151/360 reads (42%) | catalogued as rs747800974; called by mutect2, pindel, varscan2
- GJA3 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 326/704 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs981126461, CM102458, COSV53835798; called by muse, mutect2, varscan2
- GJD2 | c.362del p.P121Lfs*4 | Frame Shift Del (DEL) | VAF 253/631 reads (40%) | catalogued as rs748483263, COSV51749500; called by mutect2, pindel, varscan2
- GLI3 | c.3437T>A p.L1146H | Missense Mutation (SNP) | VAF 343/646 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV67888048; called by muse, mutect2, varscan2
- GLRA1 | c.1106G>T p.R369L (on ENST00000455880 / NM_001146040.2; = p.R361L on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 202/440 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs147471585, COSV51027148; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 166/370 reads (45%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAS | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 265/582 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); catalogued as rs763257494, COSV100005849; called by muse, mutect2, varscan2
- GNPTAB | c.2869A>G p.M957V | Missense Mutation (SNP) | VAF 207/444 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs755493862; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 140/302 reads (46%) | catalogued as rs763679060; called by mutect2, varscan2
- GPC5 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 175/386 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1182917560, COSV65605985; called by muse, mutect2, varscan2
- GPC5 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 212/461 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1248980010; called by muse, mutect2, varscan2
- GPR15 | c.880A>G p.N294D | Missense Mutation (SNP) | VAF 168/367 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV52520464; called by muse, mutect2, varscan2
- GPR63 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 132/313 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs185129489; called by muse, mutect2, varscan2
- GPR84 | c.82del p.V28Wfs*5 | Frame Shift Del (DEL) | VAF 270/689 reads (39%) | catalogued as rs759103894; called by mutect2, pindel, varscan2
- GPT | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 293/610 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs747432300; called by muse, mutect2, varscan2
- GPT | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 146/354 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.297); catalogued as rs773993974, COSV52953715; called by muse, varscan2
- GRAMD1B | c.1530del p.L511* | Frame Shift Del (DEL) | VAF 191/486 reads (39%) | catalogued as COSV99074528; called by mutect2, pindel, varscan2
- GRB10 | c.1381G>A p.A461T (on ENST00000398812; = p.A415T on NM_001001549.3) | Missense Mutation (SNP) | VAF 169/342 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV60015419; called by muse, mutect2, varscan2
- GREB1L | c.4507C>T p.R1503W | Missense Mutation (SNP) | VAF 203/446 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52551588; called by muse, mutect2, varscan2
- GRIK1 | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 174/359 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58711884; called by muse, mutect2, varscan2
- GRK1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 243/521 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as rs200986774; called by muse, mutect2, varscan2
- GRM3 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 193/410 reads (47%) | catalogued as COSV64466766; called by muse, mutect2, varscan2
- GRM6 | c.1889G>A p.G630D | Missense Mutation (SNP) | VAF 331/638 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51431979; called by muse, mutect2, varscan2
- GSDME | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 218/436 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as rs377050475; called by muse, mutect2, varscan2
- GTF2IRD1 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 203/435 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs782299708; called by muse, mutect2, varscan2
- GTF3C1 | c.3864G>T p.K1288N | Missense Mutation (SNP) | VAF 168/362 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV62243229; called by muse, mutect2, varscan2
- GUCY1A1 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 184/380 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143862431; called by muse, mutect2, varscan2
- GUCY1A2 | c.1205A>T p.K402M | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV56490301; called by muse, mutect2, varscan2
- GYPC | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 204/429 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs768335450; called by muse, mutect2, varscan2
- H2AC1 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.51); catalogued as rs1312427918, COSV51236711; called by muse, mutect2, varscan2
- H2BC9 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 152/338 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.134); catalogued as rs1379428825; called by muse, mutect2, varscan2
- HAP1 | c.1457C>T p.T486M (on ENST00000310778 / NM_001367460.1; = p.T434M on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 169/363 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs782546957, COSV57880158; called by muse, mutect2, varscan2
- HDAC6 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 392/392 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61927740; called by muse, mutect2, varscan2
- HDGFL2 | c.373del p.V125Sfs*7 | Frame Shift Del (DEL) | VAF 259/737 reads (35%) | catalogued as rs914269467; called by pindel, varscan2
- HEMGN | c.322del p.T108Lfs*7 | Frame Shift Del (DEL) | VAF 228/570 reads (40%) | catalogued as rs751768399; called by mutect2, pindel, varscan2
- HERC2 | c.13708G>A p.A4570T | Missense Mutation (SNP) | VAF 242/492 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.411); catalogued as rs1350012976; called by muse, mutect2, varscan2
- HEY1 | c.143del p.L48Wfs*9 | Frame Shift Del (DEL) | VAF 206/481 reads (43%) | catalogued as rs745485637; called by mutect2, pindel, varscan2
- HIC1 | c.1801G>A p.A601T (on ENST00000322941 / NM_001098202.1; = p.A582T on NM_006497.4) | Missense Mutation (SNP) | VAF 323/644 reads (50%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.979); catalogued as COSV53963219; called by muse, varscan2
- HIF1A | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 112/256 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100049385; called by muse, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 232/396 reads (59%) | catalogued as rs199474609; called by mutect2, varscan2
- HOXA3 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 108/1086 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs779382325, COSV57826151; called by muse, mutect2
- HOXA7 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 254/492 reads (52%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.028); catalogued as rs565645084; called by muse, mutect2, varscan2
- HOXB1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 294/581 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs750258334; called by muse, mutect2, varscan2
- HOXB9 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 423/833 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV60817571; called by muse, mutect2, varscan2
- HRH2 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 251/507 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs367866082; called by muse, mutect2, varscan2
- HRH3 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 349/579 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.186); catalogued as rs1156906048, COSV58051039; called by muse, mutect2, varscan2
- HSF4 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 174/380 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV99263561; called by muse, mutect2, varscan2
- HSPH1 | c.1481C>T p.T494M | Missense Mutation (SNP) | VAF 168/395 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs765918581, COSV60710697; called by muse, mutect2, varscan2
- HUS1B | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 66/912 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1190273257; called by muse, mutect2
- HYAL4 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 181/446 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs758644949; called by muse, mutect2, varscan2
- IDE | c.2471G>A p.R824H | Missense Mutation (SNP) | VAF 186/389 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747993929, COSV56424941; called by muse, mutect2, varscan2
- IFIH1 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 178/377 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs186942719, COSV55125491; called by muse, mutect2, varscan2
- IFNGR1 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 202/438 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV62989434; called by muse, mutect2, varscan2
- IFT122 | c.896del p.G299Vfs*71 (on ENST00000348417 / NM_052989.3; = p.G240Vfs*71 on NM_018262.4) | Frame Shift Del (DEL) | VAF 248/616 reads (40%) | catalogued as rs778534085; called by mutect2, pindel, varscan2
- IGDCC3 | c.2425C>A p.P809T | Missense Mutation (SNP) | VAF 241/501 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.227); catalogued as rs1382698847; called by muse, mutect2, varscan2
- IGF1R | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 166/339 reads (49%) | catalogued as COSV51286903; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 178/360 reads (49%) | catalogued as rs760021495; called by mutect2, varscan2
- IGFBP1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 112/764 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.592); catalogued as rs1195568130; called by muse, varscan2
- IGFBP1 | c.268del p.E90Sfs*40 | Frame Shift Del (DEL) | VAF 357/939 reads (38%) | catalogued as rs747136225; called by pindel, varscan2
- IGFBP3 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 324/726 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs1419444305; called by muse, mutect2
- IGFBP4 | c.123del p.V42Wfs*52 | Frame Shift Del (DEL) | VAF 439/894 reads (49%) | catalogued as rs778799414; called by mutect2, varscan2
- IGHG1 | c.322A>C p.T108P | Missense Mutation (SNP) | VAF 243/513 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1474544394; called by muse, mutect2, varscan2
- IGHV3-20 | c.53A>G p.Q18R | Missense Mutation (SNP) | VAF 184/446 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); catalogued as rs372438612; called by muse, mutect2, varscan2
- IGSF3 | c.2414G>A p.R805H (on ENST00000369486 / NM_001007237.3; = p.R825H on NM_001542.4) | Missense Mutation (SNP) | VAF 153/327 reads (47%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.919); catalogued as rs1441070038; called by muse, mutect2, varscan2
- IL16 | c.3722C>T p.S1241L (on ENST00000302987 / NM_172217.5; = p.S540L on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 205/468 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); catalogued as rs373629180; called by muse, mutect2, varscan2
- IL3 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 186/368 reads (51%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs183170475, COSV57308898; called by muse, mutect2, varscan2
- ILDR2 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 362/728 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1377515280, COSV54829340; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 185/388 reads (48%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, varscan2
- IMMP1L | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 111/231 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs748539826; called by muse, mutect2, varscan2
- IMP4 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 195/391 reads (50%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs777096793, COSV52091651; called by muse, mutect2, varscan2
- INHBA | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 235/462 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54220107; called by muse, mutect2, varscan2
- INPP5F | c.631dup p.W211Lfs*3 | Frame Shift Ins (INS) | VAF 150/302 reads (50%) | catalogued as rs768918635; called by mutect2, varscan2
- IPO11 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 92/220 reads (42%) | catalogued as rs1297677377, COSV57576352; called by muse, mutect2, varscan2
- IQGAP2 | c.4506-1G>T p.X1502_splice | Splice Site (SNP) | VAF 76/166 reads (46%) | catalogued as COSV99166776; called by muse, mutect2, varscan2
- IQSEC3 | c.1568C>T p.A523V (on ENST00000538872 / NM_001170738.2; = p.A220V on NM_015232.1) | Missense Mutation (SNP) | VAF 370/768 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100407975; called by muse, mutect2
- IRS2 | c.3481G>C p.V1161L | Missense Mutation (SNP) | VAF 392/767 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV65478718, COSV65481253; called by muse, mutect2, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 181/438 reads (41%) | catalogued as rs761558950; called by mutect2, varscan2
- ITGAV | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 140/278 reads (50%) | catalogued as rs778721113; called by muse, varscan2
- ITIH4 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 192/399 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV99819606; called by muse, mutect2, varscan2
- ITPR2 | c.7250del p.L2417* | Frame Shift Del (DEL) | VAF 144/290 reads (50%) | catalogued as rs1288961144; called by mutect2, varscan2
- ITSN1 | c.4225G>A p.A1409T | Missense Mutation (SNP) | VAF 233/484 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs781569279, COSV67157825; called by muse, mutect2, varscan2
- JAG2 | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 297/654 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as rs191336412; called by muse, mutect2, varscan2
- JAM3 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 153/343 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54456289; called by muse, mutect2, varscan2
- JAML | c.527G>A p.R176H (on ENST00000356289 / NM_001098526.2; = p.R166H on NM_153206.3) | Missense Mutation (SNP) | VAF 123/270 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765722769; called by muse, mutect2, varscan2
- JPH2 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 66/848 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65902699; called by muse, mutect2
- KANK4 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 240/520 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV62985323; called by muse, mutect2, varscan2
- KAZN | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 178/388 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs755820319, COSV63210399; called by muse, mutect2
- KBTBD11 | c.1278G>T p.E426D | Missense Mutation (SNP) | VAF 385/754 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57224680; called by muse, varscan2
- KBTBD13 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 377/807 reads (47%) | catalogued as rs766677668; called by muse, mutect2, varscan2
- KCNA10 | c.647del p.R216Lfs*32 | Frame Shift Del (DEL) | VAF 228/541 reads (42%) | catalogued as COSV63905147; called by mutect2, pindel, varscan2
- KCNC1 | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 311/579 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56392371; called by muse, mutect2, varscan2
- KCND1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 344/345 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs782418036, COSV54414278; called by muse, mutect2, varscan2
- KCNH1 | c.2159G>A p.R720H (on ENST00000271751 / NM_172362.3; = p.R693H on NM_002238.4) | Missense Mutation (SNP) | VAF 180/409 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.302); catalogued as rs745766834, COSV55085748; called by muse, varscan2
- KCNU1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs755168039, COSV67754940; called by muse, mutect2, varscan2
- KCTD13 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 189/408 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV58157114; called by muse, mutect2, varscan2
- KIAA0408 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 154/299 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756491042, COSV100847016, COSV64107131; called by muse, mutect2, varscan2
- KIAA1210 | c.4195G>T p.G1399* | Nonsense Mutation (SNP) | VAF 20/333 reads (6%) | catalogued as COSV101274235, COSV68178425; called by muse, mutect2
- KIAA1522 | c.2377G>A p.V793M (on ENST00000373480 / NM_001198972.2; = p.V852M on NM_020888.3) | Missense Mutation (SNP) | VAF 307/683 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV99614518; called by muse, mutect2, varscan2
- KIAA1549L | c.5234G>T p.G1745V (on ENST00000321505; = p.G2042V on NM_012194.3) | Missense Mutation (SNP) | VAF 197/408 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV58589222; called by muse, mutect2, varscan2
- KIAA1671 | c.4111C>A p.Q1371K | Missense Mutation (SNP) | VAF 169/577 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1311183718; called by muse, mutect2, varscan2
- KIAA2013 | c.1380del p.L461Cfs*74 | Frame Shift Del (DEL) | VAF 267/736 reads (36%) | catalogued as COSV64860737; called by mutect2, pindel, varscan2
- KIAA2026 | c.4507G>A p.A1503T | Missense Mutation (SNP) | VAF 199/399 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV67356763; called by muse, mutect2, varscan2
- KIF13B | c.4741G>A p.A1581T | Missense Mutation (SNP) | VAF 121/844 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs1420025061; called by muse, mutect2, varscan2
- KIF26A | c.5288G>A p.R1763H | Missense Mutation (SNP) | VAF 303/589 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs759984495, COSV59467641; called by muse, mutect2, varscan2
- KIR2DL4 | c.527G>A p.R176H (on ENST00000396284; = p.R137H on NM_001080770.2) | Missense Mutation (SNP) | VAF 330/693 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs537400112, COSV60877656; called by muse, mutect2, varscan2
- KLF16 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 417/836 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1483372317, COSV51737011; called by muse, mutect2, varscan2
- KLF5 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 286/577 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV66614131, COSV66614346; called by muse, mutect2, varscan2
- KLHL12 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 203/427 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1219640111, COSV63042853; called by muse, mutect2, varscan2
- KLHL34 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 413/413 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV65279930; called by muse, mutect2, varscan2
- KMT2B | c.7532G>A p.R2511Q | Missense Mutation (SNP) | VAF 194/391 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1232711537, COSV55819574; called by muse, mutect2, varscan2
- KREMEN2 | c.1325C>T p.A442V (on ENST00000303746 / NM_172229.3; = p.R416W on NM_024507.4) | Missense Mutation (SNP) | VAF 429/898 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV99233970; called by muse, mutect2, varscan2
- KRT14 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 211/490 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs755331521; called by muse, mutect2, varscan2
- KRT15 | c.99del p.S34Vfs*31 | Frame Shift Del (DEL) | VAF 106/268 reads (40%) | catalogued as COSV54178849; called by mutect2, pindel, varscan2
- KRT35 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 54/694 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs777060154, COSV55842576; called by muse, mutect2
- KRT71 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 335/652 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs552558218, COSV57290905; called by muse, mutect2, varscan2
- KRT79 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 193/387 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs772320719; called by muse, mutect2, varscan2
- KRTAP10-4 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 433/1708 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs782705931; called by muse, mutect2, varscan2
- KRTAP10-7 | c.450del p.C151Afs*29 | Frame Shift Del (DEL) | VAF 329/870 reads (38%) | catalogued as rs1555928560; called by mutect2, pindel, varscan2
- KRTAP5-1 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 42/852 reads (5%) | catalogued as rs763935742, COSV66299120; called by muse, mutect2
- LAMA2 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 127/266 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as rs1189105467, COSV70339983; called by muse, mutect2, varscan2
- LAMA2 | c.9223C>A p.Q3075K | Missense Mutation (SNP) | VAF 169/311 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771012835, COSV101370876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA3 | c.5467G>A p.D1823N (on ENST00000313654 / NM_198129.4; = p.D214N on NM_000227.6) | Missense Mutation (SNP) | VAF 130/281 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779345110; called by muse, mutect2, varscan2
- LAMA5 | c.8003G>A p.R2668Q | Missense Mutation (SNP) | VAF 347/655 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs967471014, COSV53361912; called by muse, mutect2, varscan2
- LAP3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 148/290 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750498172, COSV56898726; called by muse, varscan2
- LBR | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 180/377 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772650538; called by muse, mutect2, varscan2
- LEMD3 | c.2573-1G>T p.X858_splice | Splice Site (SNP) | VAF 133/263 reads (51%) | catalogued as COSV100384336; called by muse, mutect2, varscan2
- LENG8 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 227/533 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs201939037; called by muse, mutect2, varscan2
- LETM1 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 242/497 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs143969650; called by muse, mutect2, varscan2
- LGALS14 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 177/387 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.042); catalogued as COSV100648462; called by muse, mutect2, varscan2
- LILRB1 | c.49_50del p.L17Ifs*53 | Frame Shift Del (DEL) | VAF 180/636 reads (28%) | catalogued as rs753323765; called by pindel, varscan2
- LIMK2 | c.1645T>C p.C549R | Missense Mutation (SNP) | VAF 239/468 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.356); catalogued as COSV59182343; called by muse, mutect2, varscan2
- LIN37 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 184/403 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs369644711, COSV50001397; called by muse, mutect2, varscan2
- LIX1L | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 137/297 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553757906; called by muse, mutect2, varscan2
- LMAN2 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 195/422 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759347890, COSV57425358; called by muse, mutect2, varscan2
- LMBRD1 | c.719C>T p.A240V (on ENST00000649011; = p.A218V on NM_018368.4) | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.366); catalogued as rs768661855, COSV65298989; called by muse, mutect2, varscan2
- LNPK | c.104del p.N35Ifs*12 | Frame Shift Del (DEL) | VAF 98/275 reads (36%) | catalogued as rs1443101323; called by mutect2, pindel, varscan2
- LOXL3 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 232/479 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1353900393, COSV51214283; called by muse, mutect2, varscan2
- LPAR5 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 351/808 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61692332; called by muse, mutect2, varscan2
- LPIN1 | c.2383T>C p.Y795H | Missense Mutation (SNP) | VAF 166/315 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.884); catalogued as COSV56767961; called by muse, mutect2, varscan2
- LRBA | c.5356G>A p.V1786I | Missense Mutation (SNP) | VAF 169/362 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV100842324; called by muse, mutect2, varscan2
- LRIG3 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 165/338 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs867136273, COSV57862152; called by muse, mutect2, varscan2
- LRIT1 | c.1450A>G p.T484A | Missense Mutation (SNP) | VAF 281/598 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV64512707; called by muse, mutect2, varscan2
- LRP12 | c.1340del p.N447Tfs*41 | Frame Shift Del (DEL) | VAF 206/523 reads (39%) | catalogued as rs1217102319, COSV52630472; called by mutect2, pindel, varscan2
- LRP12 | c.745G>T p.G249* | Nonsense Mutation (SNP) | VAF 165/327 reads (50%) | catalogued as COSV52634522; called by muse, mutect2, varscan2
- LRP2 | c.8254C>T p.R2752* | Nonsense Mutation (SNP) | VAF 42/309 reads (14%) | catalogued as COSV55542953; called by muse, mutect2, varscan2
- LRP3 | c.2255dup p.P753Afs*12 | Frame Shift Ins (INS) | VAF 182/568 reads (32%) | catalogued as rs1230631561; called by mutect2, varscan2
- LRRC4C | c.1856G>A p.S619N | Missense Mutation (SNP) | VAF 131/300 reads (44%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as COSV53419726; called by muse, mutect2, varscan2
- LRRC63 | c.76del p.T26Pfs*14 | Frame Shift Del (DEL) | VAF 119/316 reads (38%) | catalogued as rs1319697316; called by mutect2, pindel, varscan2
- LRRC7 | c.4399C>T p.R1467W (on ENST00000651989 / NM_001370785.2; = p.R1387W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/400 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs755856495, COSV50412001; called by muse, mutect2, varscan2
- LRRC75A | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 197/401 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs1355855163; called by muse, mutect2, varscan2
- LRRC8A | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 218/412 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1225279411, COSV52184092; called by muse, mutect2, varscan2
- LRRC8C | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 160/337 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs770087026, COSV64999716; called by muse, mutect2, varscan2
- LRRC9 | c.1940dup p.N647Kfs*14 | Frame Shift Ins (INS) | VAF 118/249 reads (47%) | catalogued as rs769178849; called by mutect2, varscan2
- LRRIQ1 | c.1470del p.K490Nfs*28 | Frame Shift Del (DEL) | VAF 106/228 reads (46%) | catalogued as COSV101280733; called by mutect2, pindel, varscan2
- LRRK2 | c.3568G>T p.E1190* | Nonsense Mutation (SNP) | VAF 119/247 reads (48%) | catalogued as COSV54168242; called by muse, mutect2, varscan2
- LRRK2 | c.5183G>A p.R1728H | Missense Mutation (SNP) | VAF 145/282 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs145364431, CM081688, CM081690, COSV54145210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRTM1 | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 186/435 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765524725; called by muse, mutect2, varscan2
- LRWD1 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 164/608 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs753697304; called by muse, varscan2
- LSM10 | c.362dup p.N121Kfs*3 | Frame Shift Ins (INS) | VAF 142/380 reads (37%) | catalogued as rs768776995; called by mutect2, pindel, varscan2
- LTBP4 | c.4378G>T p.A1460S (on ENST00000308370 / NM_001042544.1; = p.A1423S on NM_003573.2) | Missense Mutation (SNP) | VAF 60/924 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.097); catalogued as COSV52585561; called by muse, mutect2
- LY9 | c.1540G>T p.G514* | Nonsense Mutation (SNP) | VAF 176/384 reads (46%) | catalogued as COSV54433550; called by muse, mutect2, varscan2
- LZTS2 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 365/746 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs924657673, COSV64651943; called by muse, mutect2, varscan2
- MAD2L1BP | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 299/542 reads (55%) | catalogued as rs777562428; called by muse, mutect2, varscan2
- MAEL | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 166/338 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV63306182; called by muse, mutect2, varscan2
- MAN2B2 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 176/416 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767305655; called by muse, varscan2
- MAP2K7 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 270/527 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV67608956; called by muse, mutect2, varscan2
- MAP3K13 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 174/392 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs902931460, COSV53988830; called by muse, varscan2
- MAP3K20 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 219/409 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59102562, COSV59103557; called by muse, mutect2, varscan2
- MAP3K9 | c.2843C>A p.T948N (on ENST00000554752 / NM_001284230.1; = p.T962N on NM_033141.4) | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV67122095; called by muse, varscan2
- MAP6 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 143/290 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774595883, COSV59075108; called by muse, mutect2, varscan2
- MARVELD2 | c.1289dup p.G431Rfs*5 | Frame Shift Ins (INS) | VAF 329/790 reads (42%) | catalogued as rs1283422805; called by mutect2, pindel, varscan2
- MAST2 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 199/424 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs749684141, COSV100787959; called by muse, mutect2, varscan2
- MAST4 | c.4558C>T p.R1520C (on ENST00000403625 / NM_001164664.2; = p.R1331C on NM_015183.3) | Missense Mutation (SNP) | VAF 342/691 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1372922287; called by muse, mutect2, varscan2
- MBOAT7 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 95/988 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1049872070, COSV55476101; called by muse, mutect2
- MBOAT7 | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 144/576 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); catalogued as rs1240560032; called by muse, mutect2, varscan2
- MCF2L2 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 200/485 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV61052362; called by muse, mutect2, varscan2
- MEDAG | c.539del p.P180Qfs*11 | Frame Shift Del (DEL) | VAF 108/282 reads (38%) | catalogued as rs1368498416, COSV66850199; called by mutect2, pindel, varscan2
- MEF2A | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1206225537; called by muse, mutect2, varscan2
- MEGF8 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 178/385 reads (46%) | catalogued as rs1222471099; called by muse, mutect2, varscan2
- MFN1 | c.401del p.K134Rfs*3 | Frame Shift Del (DEL) | VAF 81/237 reads (34%) | catalogued as rs755881517; called by mutect2, pindel, varscan2
- MFSD1 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 136/312 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs570607559; called by muse, mutect2, varscan2
- MFSD6L | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 282/556 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as COSV61002178; called by muse, varscan2
- MGA | c.3662G>A p.R1221Q | Missense Mutation (SNP) | VAF 117/219 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs772780139; called by muse, mutect2, varscan2
- MGA | c.4139G>A p.R1380Q | Missense Mutation (SNP) | VAF 109/482 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as rs376715603; called by muse, mutect2, varscan2
- MGST3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 143/291 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as rs764623433; called by muse, mutect2, varscan2
- MIDEAS | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 242/539 reads (45%) | catalogued as COSV54093577; called by muse, varscan2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 119/328 reads (36%) | catalogued as COSV67083276; called by mutect2, pindel, varscan2
- MIGA2 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 359/721 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs763100787; called by muse, mutect2, varscan2
- MITF | c.1075C>T p.R359* (on ENST00000448226 / NM_006722.3; = p.R259* on NM_000248.4) | Nonsense Mutation (SNP) | VAF 234/534 reads (44%) | catalogued as CM960963, COSV100097589; called by muse, mutect2, varscan2
- MIXL1 | c.201del p.A68Pfs*104 | Frame Shift Del (DEL) | VAF 67/485 reads (14%) | catalogued as rs1310131842; called by mutect2, pindel, varscan2
- MKI67 | c.8470C>A p.P2824T | Missense Mutation (SNP) | VAF 212/693 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as COSV64075981; called by muse, mutect2, varscan2
- MKRN1 | c.134del p.G45Afs*44 | Frame Shift Del (DEL) | VAF 366/897 reads (41%) | catalogued as rs1488398510; called by mutect2, pindel, varscan2
- MKRN3 | c.118del p.E40Nfs*21 | Frame Shift Del (DEL) | VAF 248/590 reads (42%) | catalogued as COSV100090874; called by mutect2, pindel, varscan2
- MLC1 | c.639dup p.I214Dfs*8 | Frame Shift Ins (INS) | VAF 242/585 reads (41%) | catalogued as rs1449444164; called by mutect2, pindel, varscan2
- MMP9 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 242/459 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1263490093; called by muse, mutect2, varscan2
- MRPL37 | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 179/367 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV60320964; called by muse, mutect2, varscan2
- MS4A18 | c.676G>A p.A226T (on ENST00000398983; = p.A228T on NM_001354471.1) | Missense Mutation (SNP) | VAF 205/421 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs960858474; called by muse, mutect2, varscan2
- MTCL1 | c.1846G>A p.A616T (on ENST00000306329 / NM_001378206.1; = p.A256T on NM_015210.4) | Missense Mutation (SNP) | VAF 259/539 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs757292748, COSV60403859; called by muse, varscan2
- MTCL1 | c.3154C>T p.R1052W (on ENST00000306329 / NM_001378206.1; = p.R733W on NM_015210.4) | Missense Mutation (SNP) | VAF 133/286 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60414292; called by muse, mutect2, varscan2
- MTF1 | c.2224del p.E742Rfs*90 | Frame Shift Del (DEL) | VAF 165/385 reads (43%) | catalogued as COSV65988475; called by mutect2, pindel, varscan2
- MTHFD1L | c.278del p.N93Tfs*18 | Frame Shift Del (DEL) | VAF 181/422 reads (43%) | catalogued as rs769597461; called by mutect2, pindel, varscan2
- MUC17 | c.9587C>T p.T3196I | Missense Mutation (SNP) | VAF 186/430 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV60279785; called by muse, mutect2, varscan2
- MUC2 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 322/636 reads (51%) | SIFT deleterious (0); catalogued as rs1432381237; called by muse, mutect2, varscan2
- MUC4 | c.16102G>A p.A5368T (on ENST00000463781 / NM_018406.7; = p.A1132T on NM_004532.6) | Missense Mutation (SNP) | VAF 373/1255 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs1357932793; called by muse, mutect2, varscan2
- MUC4 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 406/880 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.494); catalogued as rs1438580385; called by muse, mutect2, varscan2
- MUC4 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 388/860 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.494); catalogued as rs759575824; called by muse, mutect2, varscan2
- MUC5B | c.14254C>G p.P4752A | Missense Mutation (SNP) | VAF 346/662 reads (52%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs774333108; called by mutect2, varscan2
- MUTYH | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 234/485 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1557476104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYBPC2 | c.3323G>A p.R1108H | Missense Mutation (SNP) | VAF 58/663 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375655410; called by muse, mutect2
- MYBPH | c.1384del p.E462Rfs*114 | Frame Shift Del (DEL) | VAF 212/528 reads (40%) | catalogued as COSV55141095; called by mutect2, pindel, varscan2
- MYCBPAP | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 259/545 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761217163; called by muse, mutect2, varscan2
- MYH11 | c.5241G>T p.E1747D | Missense Mutation (SNP) | VAF 310/632 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.308); catalogued as COSV55544409; called by muse, mutect2, varscan2
- MYH2 | c.4148C>T p.T1383M | Missense Mutation (SNP) | VAF 125/315 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1456388384, COSV55446746; called by muse, mutect2, varscan2
- MYH4 | c.3635A>G p.D1212G | Missense Mutation (SNP) | VAF 171/395 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs141172847; called by muse, mutect2, varscan2
- MYL2 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 125/287 reads (44%) | catalogued as rs1305020660; called by muse, varscan2
- MYO15A | c.9665G>A p.R3222H | Missense Mutation (SNP) | VAF 191/383 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201712137, COSV99233311; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO19 | c.2320C>T p.R774* (on ENST00000614623 / NM_001163735.1; = p.R574* on NM_025109.5) | Nonsense Mutation (SNP) | VAF 174/640 reads (27%) | catalogued as rs376989253; called by muse, varscan2
- MYO1G | c.454C>A p.R152S | Missense Mutation (SNP) | VAF 251/483 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV51853262, COSV99349192; called by muse, mutect2, varscan2
- MYOCD | c.1440del p.S481Pfs*18 | Frame Shift Del (DEL) | VAF 282/764 reads (37%) | catalogued as COSV58513333; called by pindel, varscan2
- MYOM2 | c.2374G>A p.G792S | Missense Mutation (SNP) | VAF 292/589 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs34863717, COSV50720369; called by muse, mutect2, varscan2
- NAA16 | c.1890A>T p.E630D | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769875149, COSV65127991; called by muse, mutect2, varscan2
- NAB1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 196/431 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61609085; called by muse, mutect2, varscan2
- NAV1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 194/431 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs146415554, CM137457; called by muse, mutect2, varscan2
- NBEAL2 | c.4360A>G p.T1454A | Missense Mutation (SNP) | VAF 270/556 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.441); catalogued as COSV52757772; called by muse, mutect2, varscan2
- NEB | c.4147A>G p.T1383A | Missense Mutation (SNP) | VAF 56/634 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1436726179; called by muse, mutect2
- NEDD4 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 153/296 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs367919667; called by muse, varscan2
- NFKBID | c.865C>T p.R289W (on ENST00000396901; = p.R441W on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/466 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs773657096, COSV61729046; called by muse, mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 226/454 reads (50%) | catalogued as rs1171412241, CD054388; called by mutect2, varscan2
- NIPA1 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 280/565 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV61680180; called by muse, mutect2, varscan2
- NKX3-2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 179/376 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs868029446; called by muse, varscan2
- NKX6-2 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 284/557 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569871146; called by muse, mutect2, varscan2
- NLGN1 | c.2414A>C p.N805T | Missense Mutation (SNP) | VAF 184/411 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as COSV64341894; called by muse, mutect2, varscan2
- NLGN2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 284/538 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as rs757491477, COSV56658713; called by muse, mutect2, varscan2
- NLRC3 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 227/475 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs539597311, COSV57089352; called by muse, mutect2, varscan2
- NLRP10 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 259/564 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs201964741, COSV60781159, COSV60781793; called by muse, mutect2, varscan2
- NME4 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 111/283 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs776192267; called by muse, mutect2, varscan2
- NMUR1 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 300/553 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs962529763; called by muse, mutect2, varscan2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 61/142 reads (43%) | catalogued as rs753934412; called by mutect2, pindel, varscan2
- NPBWR1 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 37/878 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); catalogued as rs939933182; called by muse, mutect2
- NPY2R | c.796del p.T266Pfs*35 | Frame Shift Del (DEL) | VAF 167/414 reads (40%) | catalogued as rs758758894; called by mutect2, pindel, varscan2
- NRG2 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 251/538 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549739291; called by muse, mutect2, varscan2
- NRG3 | c.148dup p.R50Pfs*6 | Frame Shift Ins (INS) | VAF 196/372 reads (53%) | catalogued as rs772601407; called by mutect2, varscan2
- NRG3 | c.2111C>T p.A704V (on ENST00000404547 / NM_001370084.1; = p.A680V on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 172/352 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.666); catalogued as rs367831182; called by muse, mutect2, varscan2
- NRIP1 | c.2507A>G p.D836G | Missense Mutation (SNP) | VAF 185/390 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as rs779601974; called by muse, mutect2, varscan2
- NRROS | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 269/528 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs1326793733; called by muse, mutect2, varscan2
- NRXN3 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 303/623 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs374275388; called by muse, mutect2, varscan2
- NTN4 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 216/483 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.233); catalogued as rs376168277, COSV59220679; called by muse, mutect2, varscan2
- NUDCD1 | c.1492T>A p.F498I | Missense Mutation (SNP) | VAF 149/318 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53457229; called by muse, mutect2, varscan2
- NUDT22 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 164/323 reads (51%) | catalogued as rs560431443; called by mutect2, varscan2
- NUTM1 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 221/494 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60995577; called by muse, mutect2, varscan2
- NXN | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 204/419 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs779509441; called by muse, mutect2, varscan2
- OBSCN | c.13693del p.A4565Pfs*117 | Frame Shift Del (DEL) | VAF 364/890 reads (41%) | catalogued as COSV52839582; called by mutect2, pindel, varscan2
- OCEL1 | c.289del p.R97Afs*60 | Frame Shift Del (DEL) | VAF 292/737 reads (40%) | catalogued as rs761699990; called by mutect2, pindel, varscan2
- OIT3 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 247/476 reads (52%) | catalogued as rs770133213, COSV61825631; called by muse, mutect2, varscan2
- OLFML3 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 86/603 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776489989, COSV57434919; called by muse, mutect2, varscan2
- OPLAH | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 331/707 reads (47%) | catalogued as rs782043072; called by muse, mutect2, varscan2
- OPN4 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 269/537 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs767019152; called by muse, mutect2, varscan2
- OPN5 | c.444del p.H148Qfs*22 | Frame Shift Del (DEL) | VAF 167/421 reads (40%) | catalogued as COSV55247486; called by mutect2, pindel, varscan2
- OR10A7 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 198/408 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV58278083; called by muse, mutect2, varscan2
- OR11G2 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 63/448 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.023); catalogued as COSV62131908; called by muse, mutect2, varscan2
- OR11H12 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 188/2022 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs753575541; called by muse, mutect2
- OR13H1 | c.882del p.D295Mfs*6 | Frame Shift Del (DEL) | VAF 182/256 reads (71%) | catalogued as rs766808182, COSV100088244; called by mutect2, pindel, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 180/394 reads (46%) | catalogued as rs761899382; called by mutect2, varscan2
- OR14I1 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.229); catalogued as COSV100700447; called by muse, mutect2, varscan2
- OR1S1 | c.213del p.M72Cfs*25 | Frame Shift Del (DEL) | VAF 136/415 reads (33%) | catalogued as rs761074067, COSV58706814; called by mutect2, pindel, varscan2
- OR2A1 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs573150405; called by mutect2, varscan2
- OR2AT4 | c.598del p.Q200Rfs*37 | Frame Shift Del (DEL) | VAF 216/558 reads (39%) | catalogued as rs999134663; called by mutect2, pindel, varscan2
- OR2T6 | c.433C>A p.L145M | Missense Mutation (SNP) | VAF 368/739 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV100861480; called by muse, mutect2, varscan2
- OR2W3 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 212/441 reads (48%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs767980833, COSV64457734; called by muse, mutect2
- OR4E1 | c.853del p.L285Cfs*2 | Frame Shift Del (DEL) | VAF 171/437 reads (39%) | catalogued as rs1312848030; called by mutect2, pindel, varscan2
- OR4N2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs532135396, COSV60051747, COSV60052445; called by muse, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 218/446 reads (49%) | catalogued as rs748398423; called by mutect2, varscan2
- OR52B2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 232/491 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774261038, COSV73209479; called by muse, mutect2, varscan2
- OR52W1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 240/557 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs756662426, COSV60950726; called by muse, mutect2, varscan2
- OR6K2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 182/415 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs532035184, COSV62743770; called by muse, mutect2, varscan2
- OR8B8 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 231/494 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as COSV60144479; called by muse, mutect2, varscan2
- OR8K1 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 284/631 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as rs560184936, COSV54403307; called by muse, mutect2, varscan2
- OS9 | c.789C>T p.A263= | Splice Region (SNP) | VAF 202/452 reads (45%) | catalogued as rs563206099; called by muse, mutect2, varscan2
- OSBPL5 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 253/519 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs547003210; called by muse, mutect2, varscan2
- OTOG | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 213/390 reads (55%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs774453668; called by muse, mutect2, varscan2
- OTUD7A | c.2312del p.P771Rfs*216 (on ENST00000307050 / NM_001382637.1; = p.P764Rfs*216 on NM_130901.3) | Frame Shift Del (DEL) | VAF 89/230 reads (39%) | catalogued as rs1258615864; called by mutect2, pindel, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 134/326 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by muse, mutect2, varscan2
- PAPOLG | c.399dup p.E134* | Frame Shift Ins (INS) | VAF 94/248 reads (38%) | catalogued as rs1221757758; called by mutect2, varscan2
- PAQR9 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 228/511 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV61417771; called by muse, mutect2, varscan2
- PARD6G | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 395/803 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs904200168; called by muse, mutect2, varscan2
- PARPBP | c.1679G>A p.C560Y | Missense Mutation (SNP) | VAF 138/290 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1565910730; called by muse, mutect2, varscan2
- PC | c.1936dup p.A646Gfs*19 | Frame Shift Ins (INS) | VAF 249/589 reads (42%) | catalogued as rs776366810; called by mutect2, pindel, varscan2
- PCDH1 | c.2219C>T p.A740V | Missense Mutation (SNP) | VAF 234/497 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs1201677468; called by muse, mutect2, varscan2
- PCDH7 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 249/503 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688692; called by muse, mutect2, varscan2
- PCDH8 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 336/693 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV58815291; called by muse, mutect2, varscan2
- PCDH8 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 323/732 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as rs1191118479; called by muse, mutect2, varscan2
- PCDHA13 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 151/336 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.604); catalogued as rs1345451348, COSV56476358; called by muse, mutect2, varscan2
- PCDHA13 | c.1333del p.V445Wfs*4 | Frame Shift Del (DEL) | VAF 307/586 reads (52%) | catalogued as rs1562791192; called by mutect2, varscan2
- PCDHB1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 264/557 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60631214; called by muse, mutect2, varscan2
- PCDHB13 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 182/428 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.035); catalogued as rs536260978, COSV99507161; called by muse, varscan2
- PCDHB13 | c.2194del p.L732Ffs*8 | Frame Shift Del (DEL) | VAF 225/557 reads (40%) | catalogued as rs1554288180, COSV53396232; called by mutect2, pindel, varscan2
- PCDHB15 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 253/487 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV50858060; called by muse, mutect2, varscan2
- PCDHGA4 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 251/531 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.503); catalogued as rs1228836363, COSV53968641; called by muse, mutect2, varscan2
- PCDHGA4 | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 130/468 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.099); catalogued as COSV54050986, COSV54071088; called by muse, mutect2, varscan2
- PCDHGB6 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 109/643 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs757628906, COSV53968275; called by muse, mutect2, varscan2
- PCNT | c.7918A>G p.M2640V | Missense Mutation (SNP) | VAF 141/282 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1199905581; called by muse, varscan2
- PCNX3 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 194/425 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100482613; called by muse, mutect2, varscan2
- PDCD1 | c.105dup p.T36Hfs*70 | Frame Shift Ins (INS) | VAF 283/586 reads (48%) | catalogued as rs768249210; called by mutect2, varscan2
- PDE12 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 235/500 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV60819507; called by muse, mutect2, varscan2
- PDE3A | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 412/817 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs767740035; called by muse, mutect2, varscan2
- PDX1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 318/654 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs761089644, COSV66846968; called by muse, mutect2, varscan2
- PDZD2 | c.377A>T p.K126M | Missense Mutation (SNP) | VAF 215/448 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56855660; called by muse, mutect2, varscan2
- PEG3 | c.1662G>T p.Q554H | Missense Mutation (SNP) | VAF 263/508 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1481723913; called by muse, mutect2, varscan2
- PENK | c.441C>G p.D147E | Missense Mutation (SNP) | VAF 249/555 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV59242575; called by muse, mutect2, varscan2
- PER1 | c.3266G>T p.S1089I | Missense Mutation (SNP) | VAF 202/398 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57920610; called by muse, mutect2, varscan2
- PFKP | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 177/388 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as rs150500285, COSV66899580; called by muse, mutect2, varscan2
- PGBD1 | c.2005del p.M669* | Frame Shift Del (DEL) | VAF 168/428 reads (39%) | catalogued as rs781166611; called by mutect2, pindel, varscan2
- PGBD2 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 156/300 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100251891; called by muse, mutect2, varscan2
- PHACTR3 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 376/783 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.233); catalogued as rs1374194548, COSV63026926; called by muse, mutect2, varscan2
- PIBF1 | c.33dup p.V12Sfs*5 | Frame Shift Ins (INS) | VAF 123/250 reads (49%) | catalogued as rs925772654; called by mutect2, varscan2
- PIF1 | c.329del p.P110Qfs*63 | Frame Shift Del (DEL) | VAF 476/1129 reads (42%) | catalogued as rs1209314898; called by mutect2, pindel, varscan2
- PIFO | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 155/342 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63863707; called by muse, varscan2
- PIGN | c.2381T>C p.L794S | Missense Mutation (SNP) | VAF 105/271 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV104414621; called by muse, mutect2, varscan2
- PIK3R2 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 248/796 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs1463551736; called by muse, varscan2
- PIK3R6 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 176/396 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1396636720; called by muse, mutect2, varscan2
- PITPNM2 | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 24/806 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54900233; called by muse, mutect2
- PITPNM3 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 279/582 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241778920, COSV99338601; called by muse, mutect2, varscan2
- PKD2 | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 226/455 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs370489860, CM127163; called by muse, mutect2, varscan2
- PKNOX2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 147/330 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750281653, COSV53545465; called by muse, mutect2, varscan2
- PKP3 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 342/709 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs528553438; called by muse, mutect2, varscan2
- PLA2G5 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 221/485 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs755878705, COSV100908231; called by muse, mutect2, varscan2
- PLA2G7 | c.948dup p.I317Yfs*4 | Frame Shift Ins (INS) | VAF 131/329 reads (40%) | catalogued as rs1363340574; called by mutect2, pindel, varscan2
- PLCH2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 407/817 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745634767; called by muse, mutect2, varscan2
- PLCL1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 236/462 reads (51%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs370610240; called by muse, mutect2, varscan2
- PLEC | c.13081G>A p.A4361T (on ENST00000322810 / NM_201380.4; = p.A4251T on NM_000445.5) | Missense Mutation (SNP) | VAF 309/641 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs781292412, COSV59643206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLVAP | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 301/599 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs749339163; called by muse, mutect2, varscan2
- PLXDC2 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 200/442 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101023156, COSV65909888; called by muse, varscan2
- PLXNA4 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 197/426 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779656758, COSV100324699, COSV58106366; called by muse, mutect2, varscan2
- PLXND1 | c.955G>C p.A319P | Missense Mutation (SNP) | VAF 469/937 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1323593306; called by muse, mutect2
- PNPT1 | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs200016391; called by muse, mutect2, varscan2
- POLE2 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 125/293 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs767820176, COSV53558872; called by muse, mutect2, varscan2
- POLR2I | c.318C>T p.D106= | Splice Region (SNP) | VAF 172/398 reads (43%) | catalogued as rs9288; called by muse, mutect2, varscan2
- POLR3E | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 59/397 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs762820377; called by muse, mutect2, varscan2
- POLRMT | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 179/370 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.27); catalogued as rs372491457; called by muse, mutect2, varscan2
- POM121L12 | c.369del p.L124Cfs*14 | Frame Shift Del (DEL) | VAF 308/816 reads (38%) | catalogued as rs765688315, COSV68693949; called by mutect2, pindel, varscan2
- POMC | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 230/451 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as rs866305615; called by muse, mutect2, varscan2
- POTEM | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 64/484 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1203372793; called by muse, varscan2
- PPARA | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 225/454 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1251030535; called by muse, mutect2, varscan2
- PPFIA1 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 231/469 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs143247748; called by muse, mutect2, varscan2
- PPIL2 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 277/559 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868365905; called by muse, mutect2, varscan2
- PPM1K | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 174/379 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99901119; called by muse, mutect2, varscan2
- PPOX | c.1046A>T p.D349V | Missense Mutation (SNP) | VAF 184/388 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM981618; called by muse, mutect2, varscan2
- PPP1R10 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 26/780 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs918460762; called by muse, mutect2
- PPP1R27 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 327/657 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs756452367, COSV57672420; called by muse, mutect2, varscan2
- PPP1R3C | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 194/428 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747738928, COSV53288098; called by muse, mutect2, varscan2
- PPP2R2D | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 304/632 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs375295573; called by muse, mutect2, varscan2
- PRAME | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 207/462 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as rs150825394; called by muse, mutect2, varscan2
- PRDM16 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 497/1008 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs374937969; called by muse, mutect2, varscan2
- PRDM2 | c.4942C>G p.P1648A | Missense Mutation (SNP) | VAF 192/369 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV99340679; called by muse, varscan2
- PRDM9 | c.544A>G p.S182G | Missense Mutation (SNP) | VAF 129/291 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs754017953; called by muse, mutect2, varscan2
- PRELP | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 354/738 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1220966063, COSV58114954; called by muse, mutect2, varscan2
- PREP | c.719G>A p.R240H (on ENST00000369110; = p.R306H on NM_002726.5) | Missense Mutation (SNP) | VAF 219/439 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs376174942; called by muse, mutect2, varscan2
- PRKCE | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 210/388 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs144454815, COSV100079548; called by muse, mutect2, varscan2
2,433 further variants in this file (1,608 protein-altering or splice-affecting, 681 silent, 144 other) are not listed here.
